Surgical pathology report (de-identified scan), TCGA case TCGA-MA-AA43, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-MA-AA43-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY

Entry Date

Component Results

Component
Surgical Pathology
(note)

ICD O-3
Carcinoma, squamous cell NOS
8070/3
Site: Cervix NOS
C53.9
4/11/14

Hospital Number
Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ADDENDUM- IMMUNOHISTOCHEMISTRY

Interpretation

Immunohistochemical stains with appropriate controls were performed on block A1 and A3. The poorly differentiated squamous carcinoma is positive for P63 and CK5/6(squamous markers). The adenocarcinoma is positive for CEA, negative for ER and vimentin. Both tumors are strongly positive for P16.

The immuno-staining results support the original diagnosis: invasive cervical adenocarcinoma and poorly differentiated squamous carcinoma.

End of Addendum Report or Additional Results

Staff Pathologist

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- * - INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH A DEPTH OF INVASION OF 2 MM.
- INVASIVE ADENOCARCINOMA OF CERVIX, MODERATELY DIFFERENTIATED WITH GREATEST TUMOR THICKNESS 3MM
- SEE COMMENT

*Px T35, 100%
squamous tumor
sent to BCR.*

Comment

Immuno-stains of P16, CEA, ER, vimentin, p63 and Ck5/6 were requested on block 1 and 3. The results will be followed in an addendum report. Dr. is notified on

Pertinent Clinical Information

Not provided.

Specimen(s) and Procedure: Cervical biopsy.

Gross Description

Received in formalin, labeled with the patient's name and medical record number are five pieces of tan-white to pink-red fragments ranging from 0.5 x 0.3 x 0.2 cm to 0.7 x 0.5 x 0.5 cm. The specimen is sectioned and entirely submitted in cassettes A1-A3.

[page 2 of 3]
Pathology Resident

Microscopic Description

Biopsy shows moderately differentiated adenocarcinoma and poorly differentiated squamous cell carcinoma of the cervix. There are glandular formations as well as sheet-like areas with squamous features. There are multiple mitoses and pleomorphic nuclei with prominent red nucleoli. One biopsy endocervical fragment shows is entirely replaced by tumor with the greatest thickness of 3 mm.

****Electronically Signed Out****

Staff Pathologist

Result History

SURGICAL PATHOLOGY (Order) on Order Result History Report.

Lab Information

Resulting Lab

Order Information

Order Date Order Time

Result Information

Result Date and Time	Status	Priority
	Edited Result - FINAL	Routine

Received Date/Time

Received Date Received Time

Order Providers

Authorizing Provider Encounter Provider

Encounter

[View Encounter](#)

Order: SURGICAL PATHOLOGY (Order

Administration Details

No Administrations
Recorded

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
	None		None

Order Details

Frequency	Duration	Priority	Order Class
None	None	Routine	Normal

Quantity

Ordering Quantity
1

Comments

Ordered by

[page 3 of 3]
Collection Information

Collection Date

Collection Time

Resulting Agency

Provider Information

Ordering User

Authorizing Provider
Unknown, Provider

Attending Provider(s)

Order-Level Documents:

There are no order-level documents.

Encounter[View Encounter](#)**Orders Needing Specimen Collection**

** None **

Criteria	pw 2/18/14	Yes	No

Source: NCI Genomic Data Commons file 43854248-18a3-4aae-ab61-00192f419b06 (TCGA-MA-AA43.662EBBFF-1A0B-4217-8E3D-C453AAA4BDAD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).